Somatic mutation profile of tumor specimen 7557b796-f11c-4077-a1af-b249c8 (aliquot 7557b796-f11c-4077-a1af-b249c8_D6_1) from CPTAC case 16BR012, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 40.0 years (14,599 days).
Specimen 7557b796-f11c-4077-a1af-b249c8: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 82329b78-4dc2-4e04-9561-e4ff0928cd73.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen c7c982b6-8d9a-474d-82ba-81e59d (Blood Derived Normal), aliquot c7c982b6-8d9a-474d-82ba-81e59d_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8ac7bb44-79d5-4cc0-885a-51595a0aa7b1

The open-access MAF lists 225 somatic variants for this specimen: 143 protein-altering or splice-affecting, 59 silent, 23 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 124, Silent 59, Intron 16, Nonsense Mutation 12, 5'UTR 4, Frame Shift Del 3, 3'UTR 2, In Frame Del 1, Frame Shift Ins 1, In Frame Ins 1, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXL4 | c.1304G>A p.R435Q | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as rs754142863, CM159511, CM159512, COSV100014015; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 58/171 reads (34%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCB1 | c.2342G>C p.G781A | Missense Mutation (SNP) | VAF 52/404 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV55952154, COSV99714434; called by muse, mutect2, varscan2
- AGO3 | c.1396G>C p.E466Q | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV55790614, COSV55792026; called by muse, mutect2, varscan2
- AHNAK | c.8472G>C p.K2824N | Missense Mutation (SNP) | VAF 30/190 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57210584; called by muse, mutect2, varscan2
- BCOR | c.455C>T p.P152L | Missense Mutation (SNP) | VAF 51/288 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375342424, COSV100653732; called by muse, mutect2, varscan2
- BRD1 | c.1256C>T p.T419M | Missense Mutation (SNP) | VAF 49/377 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.092); catalogued as rs372984514; called by muse, mutect2, varscan2
- CASD1 | c.1711C>T p.Q571* | Nonsense Mutation (SNP) | VAF 13/82 reads (16%) | catalogued as rs1430421057; called by muse, mutect2, varscan2
- CCDC88B | c.1958C>T p.S653L | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs753464541; called by muse, mutect2, varscan2
- CNDP2 | c.1222G>C p.E408Q | Missense Mutation (SNP) | VAF 20/341 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.139); catalogued as COSV60840415; called by muse, mutect2
- CRB1 | c.1856G>A p.G619E | Missense Mutation (SNP) | VAF 44/980 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.06); catalogued as COSV66329215; called by muse, mutect2
- DLL3 | c.1835C>T p.S612F | Missense Mutation (SNP) | VAF 34/246 reads (14%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.039); catalogued as rs1160237228; called by muse, mutect2, varscan2
- DNAAF2 | c.1267C>A p.P423T | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.011); catalogued as COSV53568342; called by muse, mutect2
- ESPNL | c.2137G>A p.D713N | Missense Mutation (SNP) | VAF 117/322 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs547257895; called by muse, mutect2, varscan2
- FBXO4 | c.1160G>C p.R387T | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.035); catalogued as COSV55851738; called by muse, mutect2, varscan2
- FRMPD1 | c.2840G>A p.R947Q | Missense Mutation (SNP) | VAF 56/412 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.053); catalogued as rs373579365; called by muse, mutect2, varscan2
- FXR2 | c.367C>T p.R123W | Missense Mutation (SNP) | VAF 16/151 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV51518262; called by muse, mutect2, varscan2
- GTF2H2C | c.422G>A p.G141E | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs756750605; called by muse, varscan2
- HMCN1 | c.16478G>A p.R5493K | Missense Mutation (SNP) | VAF 60/570 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV54895074; called by muse, mutect2, varscan2
- MAP3K1 | c.4187C>T p.A1396V | Missense Mutation (SNP) | VAF 137/336 reads (41%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.955); catalogued as COSV68127351; called by muse, mutect2, varscan2
- MARK4 | c.671C>T p.P224L | Missense Mutation (SNP) | VAF 43/281 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); catalogued as rs1328035585; called by muse, mutect2, varscan2
- MINDY4 | c.143G>A p.R48Q | Missense Mutation (SNP) | VAF 17/157 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747484902, COSV54671757; called by muse, mutect2, varscan2
- MKI67 | c.1268G>A p.R423K | Missense Mutation (SNP) | VAF 21/208 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.746); catalogued as COSV100896836; called by muse, mutect2
- NOC2L | c.619C>G p.L207V | Missense Mutation (SNP) | VAF 36/204 reads (18%) | SIFT tolerated (0.62); PolyPhen benign (0.036); catalogued as rs536809464; called by mutect2, varscan2
- NOS1 | c.3898G>A p.E1300K | Missense Mutation (SNP) | VAF 59/179 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV100501584, COSV57607538; called by muse, mutect2, varscan2
- OGDH | c.2620G>A p.E874K | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.06); catalogued as rs567676133; called by muse, mutect2, varscan2
- OLFML2B | c.172C>T p.Q58* | Nonsense Mutation (SNP) | VAF 24/107 reads (22%) | catalogued as rs751560717; called by muse, mutect2, varscan2
- OTOGL | c.4570G>A p.D1524N (on ENST00000547103; = p.D1515N on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54013053; called by muse, mutect2
- PHYKPL | c.887C>T p.A296V | Missense Mutation (SNP) | VAF 31/192 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as rs759651226; called by muse, mutect2, varscan2
- PLCB4 | c.1988G>T p.G663V | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53794447; called by muse, mutect2
- PSMF1 | c.53G>A p.R18K | Missense Mutation (SNP) | VAF 23/142 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV55672721; called by muse, mutect2, varscan2
- RERE | c.1967C>G p.S656C | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1376047242; called by muse, mutect2, varscan2
- RUNX2 | c.1390C>T p.R464W (on ENST00000371438; = p.R442W on NM_001015051.3) | Missense Mutation (SNP) | VAF 244/774 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373218126; called by muse, mutect2, varscan2
- RUSC2 | c.3877C>T p.R1293C | Missense Mutation (SNP) | VAF 147/466 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1563876680, COSV63427711; called by muse, mutect2, varscan2
- SFXN4 | c.716G>C p.R239T | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs773000369; called by muse, mutect2, varscan2
- SMG8 | c.961C>T p.Q321* | Nonsense Mutation (SNP) | VAF 25/442 reads (6%) | catalogued as COSV99958937; called by muse, mutect2
- SPTBN4 | c.201C>A p.F67L | Missense Mutation (SNP) | VAF 13/141 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100150885; called by muse, mutect2
- SSX7 | c.403G>C p.D135H | Missense Mutation (SNP) | VAF 21/178 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.033); catalogued as COSV53341873; called by muse, mutect2, varscan2
- TDRD5 | c.1953G>C p.L651F | Missense Mutation (SNP) | VAF 28/270 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54241216; called by muse, mutect2, varscan2
- TEK | c.505G>T p.E169* | Nonsense Mutation (SNP) | VAF 57/381 reads (15%) | catalogued as COSV66230376; called by muse, mutect2, varscan2
- TEX13C | c.490C>T p.P164S | Missense Mutation (SNP) | VAF 59/418 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.149); catalogued as rs1462655736; called by muse, mutect2, varscan2
- TGFBR3L | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 39/260 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.336); catalogued as COSV55603297; called by muse, mutect2, varscan2
- THAP8 | c.514G>A p.G172R | Missense Mutation (SNP) | VAF 63/159 reads (40%) | SIFT tolerated (0.66); PolyPhen benign (0.404); catalogued as rs776227508, COSV53077976, COSV99495818; called by muse, mutect2
- THOC5 | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV63797915; called by muse, mutect2
- TNFSF9 | c.597C>G p.F199L | Missense Mutation (SNP) | VAF 39/284 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as COSV55538909; called by muse, mutect2, varscan2
- TRPM1 | c.1663C>T p.R555W | Missense Mutation (SNP) | VAF 89/424 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373261110; called by muse, mutect2, varscan2
- VAV2 | c.1559A>G p.N520S (on ENST00000371850 / NM_001134398.2; = p.N510S on NM_003371.4) | Missense Mutation (SNP) | VAF 72/196 reads (37%) | SIFT tolerated (0.44); PolyPhen benign (0.118); catalogued as rs1254038497; called by muse, mutect2, varscan2
- WDHD1 | c.923G>T p.G308V | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV62215283; called by muse, mutect2, varscan2
- ZNF155 | c.1406C>G p.S469* | Nonsense Mutation (SNP) | VAF 32/309 reads (10%) | catalogued as COSV54208163; called by muse, mutect2, varscan2
- ZNF547 | c.389G>A p.R130K | Missense Mutation (SNP) | VAF 22/251 reads (9%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.935); catalogued as rs894855046; called by muse, mutect2
- ZNF814 | c.1215A>C p.K405N | Missense Mutation (SNP) | VAF 40/299 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.405); catalogued as rs756827423; called by muse, mutect2, varscan2
- ZW10 | c.1250C>T p.S417L | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.141); catalogued as COSV99562909; called by muse, mutect2, varscan2
- ADAM21 | c.976A>T p.N326Y | Missense Mutation (SNP) | VAF 36/340 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.062); called by mutect2, varscan2
- ADGRG1 | c.1315C>G p.R439G | Missense Mutation (SNP) | VAF 76/480 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- ANKRD30A | c.1432G>A p.E478K (on ENST00000611781; = p.E422K on NM_052997.2) | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated (0.53); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- APPL1 | c.757G>A p.D253N | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ARHGAP32 | c.2839G>A p.D947N (on ENST00000310343 / NM_001378025.1; = p.D598N on NM_014715.4) | Missense Mutation (SNP) | VAF 34/299 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- ASH1L | c.2814del p.S938Rfs*11 | Frame Shift Del (DEL) | VAF 126/271 reads (46%) | called by mutect2, pindel, varscan2
- B4GALT7 | c.535G>C p.E179Q | Missense Mutation (SNP) | VAF 93/548 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- BRINP3 | c.2017A>T p.M673L | Missense Mutation (SNP) | VAF 81/450 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- BTBD19 | c.870C>G p.F290L | Missense Mutation (SNP) | VAF 28/184 reads (15%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- C10orf88 | c.559G>C p.D187H | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.022); called by muse, mutect2
- CALHM6 | c.802C>T p.P268S | Missense Mutation (SNP) | VAF 22/181 reads (12%) | SIFT tolerated (0.62); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CAPN9 | c.910C>T p.Q304* | Nonsense Mutation (SNP) | VAF 29/248 reads (12%) | called by muse, mutect2, varscan2
- CCDC168 | c.20287C>G p.Q6763E | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- CDH8 | c.926C>T p.A309V | Missense Mutation (SNP) | VAF 11/134 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); called by muse, mutect2
- CSF1R | c.1354G>A p.D452N | Missense Mutation (SNP) | VAF 30/225 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- CSNK1A1 | c.404G>A p.R135K | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DDX50 | c.1372G>T p.D458Y | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DGCR6L | c.169G>C p.D57H | Missense Mutation (SNP) | VAF 16/192 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2
- DMXL1 | c.7921G>C p.D2641H | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- DNMT1 | c.1512G>C p.E504D | Missense Mutation (SNP) | VAF 55/497 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); called by muse, varscan2
- DOCK7 | c.879G>C p.K293N | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- DOP1B | c.6729G>C p.L2243F | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ELMOD1 | c.924G>C p.K308N | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT tolerated (0.48); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ESPN | c.376C>T p.H126Y | Missense Mutation (SNP) | VAF 41/260 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- FBF1 | c.1411G>C p.E471Q (on ENST00000586717; = p.E485Q on NM_001319193.1) | Missense Mutation (SNP) | VAF 23/161 reads (14%) | SIFT tolerated (0.72); PolyPhen benign (0.151); called by muse, mutect2, varscan2
- FMO1 | c.125G>A p.R42K | Missense Mutation (SNP) | VAF 10/178 reads (6%) | SIFT tolerated (0.38); PolyPhen benign (0.095); called by muse, mutect2
- FOXA1 | c.1247_1252delinsTATACGAAC p.D416_K418delinsVYEQ | In Frame Ins (INS) | VAF 54/425 reads (13%) | called by pindel, varscan2*
- FOXA1 | c.797_808delinsCAAGT p.F266Sfs*53 | Frame Shift Del (DEL) | VAF 28/135 reads (21%) | called by pindel, varscan2*
- FOXD4L5 | c.946C>T p.R316C | Missense Mutation (SNP) | VAF 64/1072 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.12); called by muse, mutect2
- GMPPA | c.356C>G p.S119C | Missense Mutation (SNP) | VAF 35/205 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- GPD1 | c.577G>C p.E193Q | Missense Mutation (SNP) | VAF 19/151 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- H3C12 | c.91C>G p.P31A | Missense Mutation (SNP) | VAF 9/141 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.03); called by muse, mutect2
- HAUS6 | c.1771G>A p.E591K | Missense Mutation (SNP) | VAF 13/123 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); called by muse, mutect2
- HSPA6 | c.1336G>A p.E446K | Missense Mutation (SNP) | VAF 55/469 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- HTT | c.7007dup p.A2338Sfs*17 | Frame Shift Ins (INS) | VAF 15/70 reads (21%) | called by mutect2, pindel, varscan2
- IPO5 | c.2152G>A p.G718S | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- KDM6A | c.3187A>C p.S1063R | Missense Mutation (SNP) | VAF 33/195 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- KHDC4 | c.1479C>G p.F493L | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- LAMA1 | c.5647G>A p.D1883N | Missense Mutation (SNP) | VAF 47/325 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- LCA5 | c.820C>T p.L274F | Missense Mutation (SNP) | VAF 22/172 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- LMO7 | c.3580G>A p.V1194I (on ENST00000357063; = p.V875I on NM_005358.5) | Missense Mutation (SNP) | VAF 28/124 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- LOX | c.730T>G p.C244G | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRATD2 | c.437A>C p.H146P | Missense Mutation (SNP) | VAF 53/349 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- MAFG | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 41/166 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MAP3K1 | c.1921_1941delinsT p.M641Lfs*49 | Frame Shift Del (DEL) | VAF 31/221 reads (14%) | called by pindel, varscan2*
- MED16 | c.1128C>G p.F376L | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- MROH8 | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MUC2 | c.1996G>A p.V666I | Missense Mutation (SNP) | VAF 97/289 reads (34%) | SIFT tolerated (0.45); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MVD | c.692C>T p.S231F | Missense Mutation (SNP) | VAF 42/205 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- NKAP | c.1108G>A p.E370K | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NOC2L | c.442C>A p.P148T | Missense Mutation (SNP) | VAF 35/206 reads (17%) | SIFT tolerated (0.55); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- PCDHA9 | c.492G>C p.E164D | Missense Mutation (SNP) | VAF 74/412 reads (18%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- PIK3CA | c.27_59del p.E9_I20delinsD | In Frame Del (DEL) | VAF 13/50 reads (26%) | called by mutect2, pindel, varscan2
- PLCD4 | c.1626C>G p.H542Q | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- PLEC | c.7771G>A p.E2591K (on ENST00000322810 / NM_201380.4; = p.E2481K on NM_000445.5) | Missense Mutation (SNP) | VAF 76/418 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- PLEKHG5 | c.1153G>C p.E385Q (on ENST00000400915 / NM_001042663.3; = p.E348Q on NM_020631.6) | Missense Mutation (SNP) | VAF 10/268 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PLXNA1 | c.3373G>A p.E1125K | Missense Mutation (SNP) | VAF 66/680 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); called by muse, mutect2
- PLXNA3 | c.2676G>A p.E892= | Splice Region (SNP) | VAF 37/256 reads (14%) | called by muse, mutect2, varscan2
- PLXNB3 | c.4063G>C p.E1355Q | Missense Mutation (SNP) | VAF 41/189 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- PNPLA3 | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 32/214 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- POLR2A | c.5762C>T p.P1921L | Missense Mutation (SNP) | VAF 47/148 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- PPL | c.3471G>C p.K1157N | Missense Mutation (SNP) | VAF 30/234 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- PRDM4 | c.602C>T p.T201I | Missense Mutation (SNP) | VAF 86/588 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- RCSD1 | c.597G>T p.K199N | Missense Mutation (SNP) | VAF 15/237 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); called by muse, mutect2
- RERE | c.3399C>G p.F1133L | Missense Mutation (SNP) | VAF 33/194 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- RERE | c.2063C>T p.S688L | Missense Mutation (SNP) | VAF 21/150 reads (14%) | SIFT tolerated, low confidence (0.21); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ROPN1L | c.31C>T p.Q11* | Nonsense Mutation (SNP) | VAF 25/123 reads (20%) | called by muse, mutect2, varscan2
- RPL5 | c.891C>G p.S297R | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- SBNO2 | c.808C>T p.Q270* | Nonsense Mutation (SNP) | VAF 54/303 reads (18%) | called by muse, mutect2, varscan2
- SLC22A11 | c.1576G>A p.D526N | Missense Mutation (SNP) | VAF 18/224 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.811); called by muse, mutect2
- SLC2A11 | c.331C>G p.L111V (on ENST00000345044 / NM_001024938.4; = p.L118V on NM_030807.5) | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- SPATA31A1 | c.148C>T p.R50C | Missense Mutation (SNP) | VAF 13/216 reads (6%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.832); called by muse, mutect2
- SSH2 | c.1470G>C p.Q490H | Missense Mutation (SNP) | VAF 33/323 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SYT2 | c.18G>C p.K6N | Missense Mutation (SNP) | VAF 23/185 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.185); called by mutect2, varscan2
- SZT2 | c.8227G>A p.E2743K (on ENST00000634258 / NM_001365999.1; = p.E2686K on NM_015284.4) | Missense Mutation (SNP) | VAF 29/177 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- TEP1 | c.1639C>T p.L547F | Missense Mutation (SNP) | VAF 33/149 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- THOC2 | c.352G>C p.V118L | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.58); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TMEM132C | c.1984G>A p.D662N | Missense Mutation (SNP) | VAF 29/134 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TMEM214 | c.1730C>G p.S577C | Missense Mutation (SNP) | VAF 29/198 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- TP53I13 | c.521C>T p.A174V | Missense Mutation (SNP) | VAF 71/385 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- TRIP12 | c.4010C>A p.S1337* | Nonsense Mutation (SNP) | VAF 29/222 reads (13%) | called by muse, mutect2, varscan2
- TUT7 | c.4373G>C p.R1458T | Missense Mutation (SNP) | VAF 13/132 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- UMODL1 | c.1786C>T p.Q596* | Nonsense Mutation (SNP) | VAF 66/460 reads (14%) | called by muse, mutect2, varscan2
- XPR1 | c.1889C>G p.S630C | Missense Mutation (SNP) | VAF 24/352 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- ZBTB45 | c.694C>G p.Q232E | Missense Mutation (SNP) | VAF 47/343 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ZFHX4 | c.5761G>T p.V1921F | Missense Mutation (SNP) | VAF 32/160 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); called by muse, mutect2, varscan2
- ZNF182 | c.550G>A p.D184N | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF281 | c.2449C>T p.Q817* | Nonsense Mutation (SNP) | VAF 25/299 reads (8%) | called by muse, mutect2
- ZNF850 | c.2598G>C p.E866D | Missense Mutation (SNP) | VAF 39/328 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- ZNF850 | c.2344G>T p.E782* | Nonsense Mutation (SNP) | VAF 40/328 reads (12%) | called by muse, varscan2
- ZZEF1 | c.7847T>C p.V2616A | Missense Mutation (SNP) | VAF 57/389 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- ACSS2 | c.1737G>A p.L579= | Silent (SNP) | VAF 18/230 reads (8%) | called by muse, mutect2
- ADAMTS10 | c.471G>A p.L157= | Silent (SNP) | VAF 17/115 reads (15%) | called by muse, mutect2, varscan2
- ADAMTS7 | c.4935C>T p.F1645= | Silent (SNP) | VAF 8/102 reads (8%) | called by muse, mutect2
- ADSS2 | c.1152C>T p.I384= | Silent (SNP) | VAF 7/90 reads (8%) | catalogued as COSV100836796; called by muse, mutect2
- CCDC146 | c.993C>T p.I331= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as rs1428668674; called by muse, mutect2, varscan2
- CDCA8 | c.441A>G p.P147= | Silent (SNP) | VAF 14/34 reads (41%) | called by muse, mutect2, varscan2
- CELSR1 | c.5182C>T p.L1728= | Silent (SNP) | VAF 40/136 reads (29%) | called by muse, varscan2
- CELSR1 | c.5079C>T p.L1693= | Silent (SNP) | VAF 40/114 reads (35%) | called by muse, varscan2
- CORO6 | c.966C>G p.P322= | Silent (SNP) | VAF 33/300 reads (11%) | called by muse, mutect2, varscan2
- DHX38 | c.2790C>T p.L930= | Silent (SNP) | VAF 33/275 reads (12%) | catalogued as rs377297604; called by muse, mutect2, varscan2
- DNAH8 | c.11349C>T p.L3783= | Silent (SNP) | VAF 8/128 reads (6%) | catalogued as rs1045416247; called by muse, mutect2
- DNAJC6 | c.238C>T p.L80= | Silent (SNP) | VAF 24/184 reads (13%) | called by muse, mutect2, varscan2
- DPYSL3 | c.1020G>A p.Q340= | Silent (SNP) | VAF 21/185 reads (11%) | catalogued as COSV58323550; called by muse, mutect2, varscan2
- FAM110B | c.477C>T p.F159= | Silent (SNP) | VAF 25/242 reads (10%) | catalogued as rs1405390365, COSV64066623; called by muse, mutect2, varscan2
- FLVCR1 | c.1248T>C p.F416= | Silent (SNP) | VAF 29/236 reads (12%) | called by muse, mutect2, varscan2
- FRYL | c.5001C>G p.L1667= | Silent (SNP) | VAF 7/39 reads (18%) | called by muse, mutect2, varscan2
- GATB | c.855C>T p.I285= | Silent (SNP) | VAF 9/90 reads (10%) | catalogued as COSV99859236; called by muse, mutect2, varscan2
- GMPPA | c.165C>G p.L55= | Silent (SNP) | VAF 9/94 reads (10%) | called by muse, mutect2, varscan2
- GMPPA | c.534C>T p.I178= | Silent (SNP) | VAF 22/191 reads (12%) | called by muse, mutect2, varscan2
- GYG2 | c.1314C>T p.L438= | Silent (SNP) | VAF 17/109 reads (16%) | catalogued as COSV58550127; called by muse, mutect2, varscan2
- HEATR4 | c.3004C>T p.L1002= | Silent (SNP) | VAF 26/168 reads (15%) | catalogued as rs1332019797, COSV100620223; called by muse, mutect2, varscan2
- HERC1 | c.1866G>C p.G622= | Silent (SNP) | VAF 6/34 reads (18%) | called by muse, varscan2
- HSPA14 | c.1056C>T p.F352= | Silent (SNP) | VAF 18/170 reads (11%) | called by muse, mutect2, varscan2
- IKBKE | c.1404C>T p.L468= | Silent (SNP) | VAF 28/366 reads (8%) | called by muse, mutect2
- ILF3 | c.981C>T p.F327= | Silent (SNP) | VAF 21/131 reads (16%) | catalogued as rs201772863, COSV51555940; called by muse, mutect2, varscan2
- KLHDC4 | c.258C>T p.F86= | Silent (SNP) | VAF 16/131 reads (12%) | called by muse, mutect2, varscan2
- KRT76 | c.174C>G p.L58= | Silent (SNP) | VAF 72/444 reads (16%) | catalogued as COSV60120995; called by muse, mutect2, varscan2
- LTBP4 | c.2349C>T p.F783= (on ENST00000308370 / NM_001042544.1; = p.F746= on NM_003573.2) | Silent (SNP) | VAF 59/378 reads (16%) | called by muse, mutect2, varscan2
- MAP1LC3C | c.192G>C p.L64= | Silent (SNP) | VAF 12/116 reads (10%) | called by muse, mutect2
- MAP6 | c.2010G>A p.K670= | Silent (SNP) | VAF 37/339 reads (11%) | catalogued as COSV59075210; called by muse, mutect2, varscan2
- MATN1 | c.102C>G p.L34= | Silent (SNP) | VAF 44/232 reads (19%) | called by muse, mutect2, varscan2
- NAALADL2 | c.210G>A p.E70= | Silent (SNP) | VAF 29/224 reads (13%) | called by muse, mutect2, varscan2
- NHS | c.4593C>T p.L1531= | Silent (SNP) | VAF 27/236 reads (11%) | catalogued as rs1162718106; called by muse, mutect2, varscan2
- NLRC5 | c.4681C>T p.L1561= | Silent (SNP) | VAF 34/229 reads (15%) | called by muse, mutect2, varscan2
- NPL | c.687G>A p.Q229= | Silent (SNP) | VAF 22/382 reads (6%) | called by muse, mutect2
- NRDE2 | c.1278G>A p.Q426= | Silent (SNP) | VAF 17/138 reads (12%) | catalogued as rs1264286819; called by muse, mutect2, varscan2
- NRROS | c.933C>T p.T311= | Silent (SNP) | VAF 39/319 reads (12%) | catalogued as rs1479119230, COSV100145600; called by muse, mutect2, varscan2
- OR5L2 | c.912G>A p.V304= | Silent (SNP) | VAF 28/91 reads (31%) | catalogued as COSV65724071; called by muse, varscan2
- PHKA1 | c.1560C>T p.F520= | Silent (SNP) | VAF 49/230 reads (21%) | catalogued as rs782592114; called by muse, varscan2
- PILRB | c.33C>T p.L11= | Silent (SNP) | VAF 27/247 reads (11%) | catalogued as rs1475236708; called by muse, mutect2, varscan2
- RAB43 | c.27G>A p.G9= | Silent (SNP) | VAF 14/130 reads (11%) | catalogued as rs766970909; called by muse, mutect2, varscan2
- RIPPLY3 | c.324G>A p.T108= | Silent (SNP) | VAF 22/214 reads (10%) | catalogued as rs756277029, COSV61566699; called by muse, mutect2
- RNF123 | c.2019C>T p.L673= | Silent (SNP) | VAF 36/422 reads (9%) | called by muse, mutect2
- SART1 | c.870G>A p.V290= | Silent (SNP) | VAF 30/250 reads (12%) | called by muse, mutect2, varscan2
- SEC14L6 | c.984G>A p.Q328= | Silent (SNP) | VAF 35/239 reads (15%) | called by muse, mutect2, varscan2
- SELE | c.1728C>T p.L576= | Silent (SNP) | VAF 19/187 reads (10%) | called by muse, mutect2
- SEPHS1 | c.324C>T p.L108= | Silent (SNP) | VAF 21/149 reads (14%) | catalogued as COSV100525713; called by muse, mutect2, varscan2
- SFMBT1 | c.576G>A p.L192= | Silent (SNP) | VAF 18/156 reads (12%) | called by muse, mutect2, varscan2
- SFMBT1 | c.414G>C p.L138= | Silent (SNP) | VAF 15/76 reads (20%) | called by muse, mutect2, varscan2
- SPTLC1 | c.1413C>T p.V471= | Silent (SNP) | VAF 34/262 reads (13%) | called by muse, mutect2, varscan2
- TCAF2 | c.1242C>T p.F414= | Silent (SNP) | VAF 45/258 reads (17%) | called by mutect2, varscan2
- TLE3 | c.837G>A p.L279= | Silent (SNP) | VAF 15/73 reads (21%) | called by muse, mutect2, varscan2
- TMEM41B | c.486C>T p.F162= | Silent (SNP) | VAF 13/68 reads (19%) | called by muse, mutect2, varscan2
- TRIP10 | c.648C>T p.L216= | Silent (SNP) | VAF 15/164 reads (9%) | called by muse, mutect2
- TRPM8 | c.1428C>G p.L476= | Silent (SNP) | VAF 14/144 reads (10%) | called by muse, mutect2
- UBE3C | c.2058G>A p.L686= | Silent (SNP) | VAF 17/96 reads (18%) | called by muse, mutect2, varscan2
- USP43 | c.1170C>T p.L390= | Silent (SNP) | VAF 12/142 reads (8%) | called by muse, mutect2
- XYLT2 | c.1980G>A p.R660= | Silent (SNP) | VAF 20/394 reads (5%) | called by muse, mutect2
- ZFP28 | c.1878C>T p.F626= | Silent (SNP) | VAF 22/239 reads (9%) | called by muse, mutect2
- AMBP | c.557-19C>G | Intron (SNP) | VAF 20/208 reads (10%) | called by muse, mutect2, varscan2
- ATG2A | c.825+30G>A | Intron (SNP) | VAF 9/73 reads (12%) | called by muse, mutect2, varscan2
- BNC2 | c.*6G>A | 3'UTR (SNP) | VAF 142/528 reads (27%) | called by muse, mutect2, varscan2
- BRAP | c.82+49G>A | Intron (SNP) | VAF 6/42 reads (14%) | called by muse, mutect2, varscan2
- CAMKMT | c.376+66292C>T | Intron (SNP) | VAF 6/42 reads (14%) | called by muse, mutect2, varscan2
- DHRS4L1 | n.177-427G>A | Intron (SNP) | VAF 25/205 reads (12%) | catalogued as rs540652314; called by muse, mutect2, varscan2
- DNMT1 | c.4068-15C>T | Intron (SNP) | VAF 57/407 reads (14%) | catalogued as rs1176831954; called by muse, mutect2, varscan2
- GASK1A | c.1413+124C>T | Intron (SNP) | VAF 52/350 reads (15%) | called by muse, varscan2
- GASK1A | c.1413+130C>T | Intron (SNP) | VAF 50/348 reads (14%) | called by muse, varscan2
- IGDCC4 | c.998-27G>A | Intron (SNP) | VAF 14/66 reads (21%) | called by muse, varscan2
- KIRREL1 | c.*1640C>T | 3'UTR (SNP) | VAF 50/732 reads (7%) | catalogued as rs767007463; called by muse, mutect2
- KLK14 | c.-11C>T | 5'UTR (SNP) | VAF 20/203 reads (10%) | catalogued as rs1391429349; called by muse, mutect2, varscan2
- L3MBTL2 | c.-13A>G | 5'UTR (SNP) | VAF 26/98 reads (27%) | catalogued as rs753995557, COSV99346107; called by muse, mutect2, varscan2
- MLIP | c.613-10957C>T | Intron (SNP) | VAF 53/372 reads (14%) | catalogued as COSV99231033; called by muse, mutect2, varscan2
- NFYC | c.387+1167C>G | Intron (SNP) | VAF 20/170 reads (12%) | called by muse, mutect2, varscan2
- PARP1 | c.286+181G>A | Intron (SNP) | VAF 11/84 reads (13%) | called by muse, mutect2, varscan2
- PLOD3 | c.680-37G>A | Intron (SNP) | VAF 56/205 reads (27%) | called by muse, mutect2, varscan2
- REV1 | c.182-1937C>G | Intron (SNP) | VAF 15/92 reads (16%) | called by muse, mutect2, varscan2
- SHMT2 | c.-35T>C | 5'UTR (SNP) | VAF 36/103 reads (35%) | called by muse, mutect2, varscan2
- SNORD3B-1 | n.50T>C | RNA (SNP) | VAF 14/90 reads (16%) | catalogued as rs759560326; called by mutect2, varscan2
- SYNGR2 | c.478-10C>G | Intron (SNP) | VAF 44/218 reads (20%) | called by muse, mutect2, varscan2
- TRPM1 | c.2635-36C>T | Intron (SNP) | VAF 32/192 reads (17%) | catalogued as rs1435880859; called by muse, mutect2, varscan2
- ZNF775 | c.-21G>T | 5'UTR (SNP) | VAF 13/96 reads (14%) | called by muse, mutect2, varscan2
